Somatic mutation profile of tumor specimen BA2682D (aliquot aq-BA2682D) from BEATAML1.0 case 2103, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 76.0 years (27,752 days).
Specimen BA2682D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4aaa74b4-2d83-4ec8-8cf8-e71e484b6fe0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2877D (Solid Tissue Normal), aliquot aq-BA2877D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8357cd50-a5d6-4db6-a266-9eef3223ff02

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Nonsense Mutation 2, Silent 2, Intron 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM2 | c.1210C>G p.Q404E | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1272119496; called by muse, mutect2, varscan2
- CNMD | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | catalogued as COSV100937284; called by muse, mutect2
- LILRB2 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 65/145 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.027); catalogued as rs771636990, COSV58745760; called by muse, varscan2
- TET2 | c.945del p.Q317Rfs*30 | Frame Shift Del (DEL) | VAF 44/125 reads (35%) | catalogued as COSV99484131; called by mutect2, pindel, varscan2
- TET2 | c.2224C>T p.Q742* | Nonsense Mutation (SNP) | VAF 25/398 reads (6%) | catalogued as COSV54395649; called by muse, mutect2
- CCDC6 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- CHKA | c.839A>G p.Y280C | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.117); called by muse, mutect2
- DELE1 | c.1075G>A p.V359M | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EXTL3 | c.1678G>A p.A560T | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- FADS1 | c.13G>C p.A5P | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- PCBP2 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by mutect2, varscan2
- POM121 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- SPC24 | c.180G>T p.K60N | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.035); called by muse, mutect2
- ZCCHC14 | c.2678G>T p.G893V (on ENST00000268616; = p.G1030V on NM_015144.3) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- ZNF711 | c.1406G>T p.R469I | Missense Mutation (SNP) | VAF 12/369 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); called by muse, mutect2
- ANK2 | c.5604T>C p.P1868= | Silent (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- IQGAP2 | c.681A>G p.K227= | Silent (SNP) | VAF 5/114 reads (4%) | catalogued as COSV57181921; called by muse, mutect2
- INTS4 | c.2228+741_2228+748del | Intron (DEL) | VAF 30/97 reads (31%) | called by mutect2, varscan2
- NDUFB9 | c.408+124C>A | Intron (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
